Gene-level copy-number profile of tumor specimen ALCH-B1XL-TTP1-A from ALCHEMIST case ALCH-B1XL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 76.3 years (27,883 days).
Specimen ALCH-B1XL-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 154188c9-ce2d-4b2e-a5ef-84d1d732cfa9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1XL-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/23c59874-52bd-4c14-a560-ad5e6d616797

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 562; copy number 1: 33,207; copy number 2: 23,464; copy number 3: 899; copy number 4: 330; copy number 5: 274; copy number 6: 161; copy number 8: 2; copy number 15: 5.

Homozygous deletions (total copy number 0; autosomes only): 50 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:120,489,860–120,842,110, 5 genes (within-gene range 0–1): AC241952.1, U2, 7SK, NOTCH2NLR, NBPF26.
- chr4:8,022,665–8,023,126, 1 gene (within-gene range 0–1): AC097381.3.
- chr7:155,510,283–155,518,623, 1 gene (within-gene range 0–1): AC008060.2.
- chr14:100,675,930–100,679,884, 1 gene (within-gene range 0–1): AL132711.1.
- chr15:25,255,579–25,278,409, 6 genes (within-gene range 0–1): AC124303.1, SNORD115-45, SNORD115-46, SNORD115-47, SNORD115-48, SNORD109B.
- chr15:30,992,171–32,284,258, 17 genes (within-gene range 0–1): AC009562.1, TRPM1, MIR211, LINC02352, AC012236.1, KLF13, UBE2CP4, AC104759.1, OTUD7A, DEPDC1P1, AC026951.1, CHRNA7, AC079969.1, Y_RNA, AC068448.1, AC139426.3, RNU6-18P.
- chr15:41,825,099–41,894,053, 7 genes (within-gene range 0–1): AC020659.2, JMJD7, JMJD7-PLA2G4B, PLA2G4B, SPTBN5, RNA5SP393, MIR4310.
- chr15:77,568,970–77,820,900, 6 genes: AC046168.2, LINGO1, LINGO1-AS1, LINGO1-AS2, AC105133.2, AC105133.1.
- chr16:85,169,525–85,676,204, 1 gene (within-gene range 0–1): GSE1.
- chr16:85,306,226–85,659,675, 5 genes: MIR5093, AC133540.1, AC092127.2, AC092127.1, RN7SL381P.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 1,671 genes in 38 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,282,543–150,476,566, 4 genes, copy number 3: CIART, MRPS21, PRPF3, RPRD2.
- chr2:242,087,351–242,175,634, 5 genes, copy number 3–4: AC093642.2, LINC01881, CICP10, SEPTIN14P2, RPL23AP88.
- chr3:75,421,552–75,623,849, 9 genes, copy number 3 (within-gene range 2–3): FAM86DP, LINC02018, ENPP7P2, SNRPCP10, AC133041.1, RPS3AP15, AC108724.1, OR7E121P, UNC93B3.
- chr3:197,298,252–198,123,232, 31 genes, copy number 3–4 (within-gene range 2–4): DLG1-AS1, AC128709.2, AC128709.1, AC128709.3, LINC02012, BDH1, AC132008.2, AC132008.1, AC024560.2, AC024560.3, AC024560.1, AC024560.5, RUBCN, MIR922, FYTTD1, AC055764.2, LRCH3, AC055764.1, AC144530.1, IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1.
- chr5:170,861,870–171,300,015, 3 genes, copy number 3 (within-gene range 2–3): RANBP17, RN7SL623P, AC008514.2.
- chr8:94,127,162–94,475,115, 6 genes, copy number 3 (within-gene range 2–3): CDH17, AP003478.1, GEM, RPS4XP10, RAD54B, FSBP.
- chr8:118,620,498–137,092,183, 254 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr9:4,386,410–5,776,557, 45 genes, copy number 5 (within-gene range 2–5): RNU6-694P, SLC1A1, SPATA6L, AL136231.1, PLPP6, CDC37L1-DT, CDC37L1, AK3, AL353151.2, ECM1P1, AL353151.1, RCL1, KLF4P1, MIR101-2, AL158147.1, HNRNPA1P41, JAK2, CSNK1G2P1, PDSS1P1, MTND6P5, MTND1P11, MTCO1P11, MTCO2P11, MTATP6P11, MTCO3P11, MTND4P14, MTND5P14, TCF3P1, IGHEP2, INSL6, AL133547.1, INSL4, RLN2, HMGN2P31, RLN1, AL135786.2, AL135786.1, PLGRKT, RNF152P1, CD274, AL162253.2, PDCD1LG2, AL162253.1, RIC1, AL136980.1.
- chr10:55,247,755–55,597,233, 3 genes, copy number 3 (within-gene range 2–3): AC016822.1, AL355314.1, AL355314.2.
- chr10:55,667,341–65,880,289, 86 genes, copy number 3 (broad region; genes not listed).
- chr10:108,296,099–113,492,054, 68 genes, copy number 3–4 (broad region; genes not listed).
- chr10:114,431,113–115,948,999, 12 genes, copy number 4 (within-gene range 1–4): ABLIM1, AL133384.1, PPIAP19, AL137025.1, TAF9BP2, FAM160B1, RPL15P13, TRUB1, RNU6-1121P, LINC02626, ATRNL1, AC016042.1.
- chr10:123,356,450–126,798,708, 58 genes, copy number 3: LINC02641, AL160290.1, AL357127.1, GPR26, CPXM2, AC009987.1, AC068058.1, YBX2P1, AL683842.1, CHST15, OAT, NKX1-2, AL445237.1, LHPP, RPS10P18, AC068896.1, FAM53B, AL513190.1, FAM53B-AS1, EEF1AKMT2, Y_RNA, ABRAXAS2, Y_RNA, NPM1P31, AL731577.2, ZRANB1, AL731577.1, CTBP2, AL731571.1, MIR4296, MRPS21P6, RPS27P18, TEX36-AS1, TEX36, ALDOAP2, AL158835.1, EDRF1-DT, AL158835.3, AL158835.2, EDRF1, EDRF1-AS1, MMP21, UROS, MIR4484, BCCIP, DHX32, Metazoa_SRP, RNU2-42P, FANK1, GNG10P1, FANK1-AS1, ADAM12, RNA5SP328, SAR1AP2, LINC00601, C10orf90, AL589787.1, AL512272.1.
- chr11:86,649–3,637,559, 193 genes, copy number 3–5 (broad region; genes not listed).
- chr11:8,693,351–8,910,951, 1 gene, copy number 3 (within-gene range 2–3): DENND2B.
- chr11:8,768,778–10,808,940, 55 genes, copy number 3–5: AC026894.1, RNA5SP330, Y_RNA, AKIP1, C11orf16, ASCL3, Y_RNA, TMEM9B, TMEM9B-AS1, NRIP3, AC079296.1, SCUBE2, AC079296.2, MIR5691, KRT8P41, DENND5A, AP006259.1, Metazoa_SRP, TMEM41B, PRR13P2, IPO7, SNORA23, AC132192.1, AC132192.2, ZNF143, WEE1, AC122179.1, RPL23AP65, AC011979.2, AC011979.1, SWAP70, RN7SKP50, LINC02709, SBF2-AS1, SBF2, AC011092.2, RNU7-28P, AC011092.1, AC011092.3, AC100763.1, AC080023.2, AC080023.1, ADM, AMPD3, RNU6ATAC33P, MTRNR2L8, MIR4485, RNF141, IRAG1-AS1, LYVE1, IRAG1, Y_RNA, CTR9, EIF4G2, SNORD97.
- chr11:11,759,101–13,732,346, 36 genes, copy number 3–5: AC131935.1, AC104383.1, MIR8070, USP47, H3P33, DKK3, LINC02547, AC124276.1, AC124276.2, MICAL2, MIR6124, AC079329.1, AC025300.1, PARVA, AC009806.1, TEAD1, AC013549.3, AC013549.4, AC013549.2, AC013549.1, LINC00958, RASSF10-DT, RASSF10, AC013762.1, AC022878.1, ARNTL, RN7SKP151, BTBD10, AC021269.1, AC021269.2, PTH, HMGN2P36, FAR1, FAR1-IT1, RPL39P26, Y_RNA.
- chr11:14,493,783–14,643,635, 2 genes, copy number 3 (within-gene range 2–3): AC018523.2, PSMA1.
- chr11:54,591,480–54,725,816, 11 genes, copy number 4: OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P, OR4A5, OR4A6P.
- chr11:71,603,260–73,598,189, 86 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr11:76,435,559–82,817,741, 86 genes, copy number 3–4 (broad region; genes not listed).
- chr11:85,855,101–86,765,467, 21 genes, copy number 4: CCDC83, AP003128.1, SLC25A1P1, PICALM, RNU6-560P, LINC02695, FNTAP1, Metazoa_SRP, EED, MIR6755, AP003084.1, SETP17, HIKESHI, RN7SL225P, CCDC81, AP001831.1, PTP4A1P6, AP001148.1, ME3, AP003059.1, AP003059.2.
- chr11:86,832,540–86,837,615, 2 genes, copy number 4 (within-gene range 2–4): OR7E13P, AP000654.1.
- chr11:94,706,431–107,177,530, 150 genes, copy number 3–6 (within-gene range 2–6) (broad region; genes not listed).
- chr11:118,344,344–118,603,033, 15 genes, copy number 4: CD3G, UBE4A, AP001267.1, AP001267.5, ATP5MG, AP001267.4, AP001267.2, KMT2A, AP001267.3, TTC36, TMEM25, IFT46, RPL5P30, ARCN1, RNU6-1157P.
- chr11:118,700,427–118,925,608, 12 genes, copy number 3 (within-gene range 2–3): AP002954.1, RNU6-376P, AP002954.2, DDX6, AP004609.3, AP004609.2, SETP16, Y_RNA, CXCR5, AP004609.1, BCL9L, MIR4492.
- chr14:24,809,656–25,267,336, 5 genes, copy number 4: STXBP6, AL161663.2, AL161663.1, LINC02286, HMGN2P6.
- chr14:27,612,577–27,639,636, 2 genes, copy number 4 (within-gene range 2–4): LINC00645, MIR3171.
- chr14:35,468,272–36,235,608, 19 genes, copy number 5: RPS3AP4, KRT18P6, INSM2, RALGAPA1, AL137818.1, QRSL1P3, AL162311.3, NUTF2P2, BRMS1L, AL162311.1, AL162311.2, AL133304.3, AL133304.1, ILF2P2, AL133304.2, LINC00609, PTCSC3, AL162511.1, RN7SKP21.
- chr15:32,313,126–32,315,654, 1 gene, copy number 4: AC139426.1.
- chr16:88,382,959–88,440,757, 1 gene, copy number 5: ZNF469.
- chr19:34,092,561–36,246,257, 142 genes, copy number 4–6 (broad region; genes not listed).
- chr19:37,907,208–38,208,369, 1 gene, copy number 4 (within-gene range 2–4): SIPA1L3.
- chr19:38,108,500–38,636,955, 27 genes, copy number 4: AC011465.1, AC011479.3, AC011479.2, RN7SL663P, DPF1, SPINT2, PPP1R14A, AC011479.1, AC011479.4, Y_RNA, YIF1B, C19orf33, KCNK6, CATSPERG, AC005625.1, PSMD8, GGN, AC005789.1, SPRED3, FAM98C, RASGRP4, RYR1, AC067969.2, AC067969.1, MAP4K1, AC008649.1, EIF3K.
- chr19:39,776,595–40,629,818, 39 genes, copy number 3–8: LEUTX, AC005393.1, DYRK1B, MIR6719, FBL, FCGBP, PRR13P5, PSMC4, ZNF546, AC007842.1, ZNF780B, AC005614.2, ZNF780A, AC005614.1, VN1R96P, MAP3K10, TTC9B, CCNP, AKT2, AC118344.1, MIR641, RNU6-945P, C19orf47, Y_RNA, Y_RNA, PLD3, AC118344.2, MIR6796, HIPK4, PRX, SERTAD1, AC010271.2, SERTAD3, AC010271.1, BLVRB, Metazoa_SRP, SPTBN4, SHKBP1, LTBP4.
- chr19:40,691,514–40,725,784, 2 genes, copy number 3 (within-gene range 1–3): COQ8B, RNU6-195P.
- chr19:54,617,158–54,637,528, 1 gene, copy number 5 (within-gene range 2–5): LILRB1.
- chr19:54,643,889–57,398,584, 177 genes, copy number 4–15 (within-gene range 1–15) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 30,863. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
